HCMI case HCM-STAN-1113-C18 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d4e59654-f1b9-40a7-bfef-b57eaf571aef

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1952; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.7; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Sigmoid colon; Classification of tumor: primary; Age at diagnosis: 68.9 years (25,168 days); AJCC staging edition: 8th; AJCC clinical stage: Stage IIA; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Lymphatic invasion present: No; Perineural invasion present: No; Vascular invasion present: Yes; Vascular invasion type: Intramural.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 51 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 84 days; Days to treatment end: 241 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (2 entries)
- Days to follow up: 633 days (1.7 years); Disease response: Complete Response; Progression or recurrence: No.
- Follow-up contact recording only the day: day 260.

Molecular and laboratory tests
- CEA: 1 ng/mL.
- MLH1 (IHC): Positive.
- MSH2 (IHC): Positive.
- MSH6 (IHC): Positive.
- PMS2 (IHC): Positive.
- Test: Negative; Mismatch repair mutation: Yes.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 60 kg; Height: 163 cm; BMI: 22.6.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-STAN-1113-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-STAN-1113-C18-01A-01-S1-HE: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 98; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-STAN-1113-C18-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 98; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-STAN-1113-C18-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample HCM-STAN-1113-C18-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
